Gene-level copy-number profile of tumor specimen TCGA-DX-A1L4-01A from TCGA case TCGA-DX-A1L4, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.8 years (22,195 days).
Specimen TCGA-DX-A1L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d325e6b7-88c8-4b66-9bc6-9bed0d7c0b92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1L4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7d91d2f-70dc-44bf-bc08-5568a4e969f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,381; copy number 2: 57,012; copy number 3: 195; copy number 4: 20; copy number 5: 36; copy number 6: 66; copy number 7: 66; copy number 8: 2; copy number 9: 8; copy number 10: 16; copy number 11: 3; copy number 12: 5; copy number 16: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1L4-01A-12D-A26F-01): tumor purity 0.22, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 210 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:110,391,771–113,140,870, 59 genes, copy number 6–7 (within-gene range 2–7): DDO, SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P, AL360227.1, MFSD4B, AL080317.1, REV3L, AL080317.2, FCF1P5, REV3L-IT1, BRD7P4, TRAF3IP2-AS1, AL136310.1, AL008730.1, TRAF3IP2, Z97989.1, FYN, LINC02527, CCN6, TUBE1, FAM229B, LAMA4, Z99289.1, RNU6-1226P, Z99289.2, Z99289.3, LAMA4-AS1, AL365214.2, AL365214.1, RFPL4B, RPSAP45, KRT18P65, AL365214.3, AL357514.1, PA2G4P5, AL360085.1, RNU6-1163P, AL360015.1, FCF1P10, AL049695.1.
- chr12:43,560,784–43,806,328, 8 genes, copy number 5: AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr12:46,764,761–46,972,155, 2 genes, copy number 7 (within-gene range 2–7): SLC38A4, AC079906.1.
- chr12:47,593,208–47,593,440, 1 gene, copy number 6: AC004486.1.
- chr12:57,723,761–57,896,482, 19 genes, copy number 7 (within-gene range 2–7): AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1.
- chr12:58,872,149–59,064,238, 2 genes, copy number 5 (within-gene range 2–8): LRIG3, AC068305.2.
- chr12:59,322,765–59,436,874, 3 genes, copy number 7 (within-gene range 2–7): AC108721.2, AC108721.1, RNU6-279P.
- chr12:63,271,404–63,272,336, 1 gene, copy number 9: HNRNPA1P69.
- chr12:64,222,337–64,397,065, 1 gene, copy number 6 (within-gene range 2–6): AC012158.1.
- chr12:64,264,762–64,502,114, 8 genes, copy number 6 (within-gene range 2–6): C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1.
- chr12:66,302,493–66,343,643, 1 gene, copy number 6 (within-gene range 2–6): HELB.
- chr12:66,950,754–67,132,205, 3 genes, copy number 9 (within-gene range 2–9): AC073530.1, AC073530.2, RAB11AP2.
- chr12:67,443,105–67,590,771, 1 gene, copy number 8 (within-gene range 2–8): LINC02408.
- chr12:67,709,047–67,753,817, 2 genes, copy number 5: LINC02421, AC022513.1.
- chr12:68,001,394–68,001,548, 1 gene, copy number 7: RPL39P28.
- chr12:68,805,011–68,971,570, 8 genes, copy number 16 (within-gene range 2–16): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5.
- chr12:69,348,381–69,699,476, 13 genes, copy number 5–10 (within-gene range 2–10): LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:74,170,445–74,293,096, 4 genes, copy number 5: AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:75,234,740–75,390,928, 4 genes, copy number 6 (within-gene range 3–6): CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1.
- chr12:76,137,425–76,853,696, 14 genes, copy number 7 (within-gene range 2–7): AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17.
- chr12:77,021,248–77,163,638, 2 genes, copy number 5 (within-gene range 5–7): E2F7, AC079030.1.
- chr12:78,052,181–78,131,004, 2 genes, copy number 9 (within-gene range 2–9): AC073571.1, PRXL2AP1.
- chr12:80,402,178–80,680,273, 3 genes, copy number 12 (within-gene range 2–12): PTPRQ, AKIRIN1P1, AC074031.1.
- chr12:80,832,533–80,861,508, 2 genes, copy number 9: MIR617, AC078886.1.
- chr12:82,673,070–82,686,632, 1 gene, copy number 11: AC091214.1.
- chr12:88,580,531–88,602,195, 3 genes, copy number 10: AC024941.2, RNU1-117P, AC024941.1.
- chr12:90,107,739–91,193,942, 13 genes, copy number 5–12: AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1.
- chr12:94,140,077–94,307,675, 3 genes, copy number 5–7 (within-gene range 2–7): AC123567.1, PLXNC1, AC123567.2.
- chr12:95,516,560–95,673,999, 3 genes, copy number 5 (within-gene range 2–5): USP44, PGAM1P5, Y_RNA.
- chr12:100,852,331–100,859,262, 1 gene, copy number 8: AC138360.1.
- chr12:102,836,889–102,960,513, 3 genes, copy number 10 (within-gene range 2–10): PAH, AC026108.1, ASCL1.
- chr12:103,746,315–103,768,858, 1 gene, copy number 11: AC025265.1.
- chr12:108,129,288–108,250,537, 1 gene, copy number 11 (within-gene range 2–11): WSCD2.
- chr12:108,858,932–109,088,023, 7 genes, copy number 5 (within-gene range 2–5): DAO, SVOP, RNU6-361P, AC190387.1, USP30, USP30-AS1, RNA5SP372.
- chr21:24,840,550–25,361,868, 10 genes, copy number 7 (within-gene range 2–7): LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
